Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6IF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6IF-01A (Primary Tumor).

[page 1 of 2]
Document Type: Anat Path Reports
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

*** Final Report ***

(verified)

ICD-O-3
Carcinoma, squamous
cell non-keratinizing
8092/3
Site Tonsil NOS 009.9
Jt 6/12/13

Patient Name: [REDACTED] Acc #: [REDACTED]
MRN: [REDACTED] DOB: [REDACTED] Head and Neck
Location: [REDACTED] Gender: M Collected:
Client: [REDACTED] Received:
Submitting Phys: [REDACTED] Reported:

Final Surgical Pathology Report

*** ADDENDUM PRESENT ***

Addendum Diagnosis

The diagnosis remains the same.

Addendum Comment

A touch prep was performed at the time of frozen section, and supports the diagnosis listed.

Electronically Signed by .

Addendum Diagnosis

The diagnosis remains the same.

Addendum Comment

HPV by ISH is positive in this tumor.

Electronically Signed by .

Final Pathologic Diagnosis

A. TONSIL, RIGHT, BIOPSY (A1FS):
- NON-KERATINIZING SQUAMOUS CELL CARCINOMA.
- SEE COMMENT.

B. TONSIL, RIGHT, BIOPSY:
- NON-KERATINIZING SQUAMOUS CELL CARCINOMA.

[page 2 of 2]
Comment

A p16 immunohistochemical stain is performed and is strongly positive in the tumor cells. HPV16 in situ-hybridization is also performed, and will be reported as an addendum.

Electronically Signed by

Assisted by:

Addendum / Signed Out

Addendum / Signed Out

Clinical History

Right neck cancer. Right base of tongue mass. Direct laryngoscopy with biopsy.

Specimen(s) Received

A: Right tonsil

B: Right tonsil

Gross Description

Specimen A is received fresh for intraoperative consultation, labeled with the patient's name, medical record number and as "right tonsil." It consists of multiple portions of soft tissue measuring 0.5 x 0.5 x 0.4 cm in aggregate. The specimen is submitted entirely for frozen section diagnosis, then transferred to cassette "A1FS." Dictated

Specimen B is received fresh, labeled with the patient's name, medical record number and as "right tonsil." It consists of a portion of mucosa-lined soft tissue measuring 0.6 x 0.4 x 0.3 cm. The specimen is bisected and submitted entirely in cassette "B1." Dictated by

Intraoperative Consult Diagnosis

A1FS: RIGHT TONSIL BIOPSY, (FROZEN SECTION): NON-KERATINIZING SQUAMOUS CELL CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by

Pathologist:

Source: NCI Genomic Data Commons file 39f97cf9-9e0a-4a35-a577-6ab6b671712a (TCGA-QK-A6IF.7E5C541A-F493-4A86-9B02-D1CCBC4B0E22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).